FM case AD16390 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms.
https://portal.gdc.cancer.gov/cases/ded8e632-0c2c-4fb2-bfe9-4769f1289168

Female, 19.2 years: Myoepithelial carcinoma (ICD-O-3 8982/3); specimen biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
